Somatic mutation profile of tumor specimen TCGA-XY-A89B-01A (aliquot TCGA-XY-A89B-01A-11D-A435-10) from TCGA case TCGA-XY-A89B, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 35.5 years (12,955 days).
Specimen TCGA-XY-A89B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97c4c322-0a19-45ad-87b9-9e35e1125c23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XY-A89B-10A (Blood Derived Normal), aliquot TCGA-XY-A89B-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb69e405-5b32-4d11-9f8e-bf775e528add

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, RNA 2, Intron 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1000G>T p.G334W | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882028, CM134054, COSV52820679; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP13A2 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV100454022; called by muse, mutect2, varscan2
- OXLD1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.146); catalogued as rs779418641; called by muse, mutect2, varscan2
- WAC | c.63C>G p.D21E | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs770378490; called by muse, mutect2, varscan2
- AP1S1 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CAMSAP3 | c.1034A>T p.N345I | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CNOT3 | c.59A>C p.E20A | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DMXL1 | c.1573T>A p.S525T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- EIF4G3 | c.422C>T p.T141I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ERBB2 | c.2001G>C p.L667F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FAM149B1 | c.1483C>T p.H495Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- FMN2 | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FZD8 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- KDM2A | c.3386G>A p.C1129Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KRT9 | c.269T>C p.F90S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.10123C>G p.L3375V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- RAB42 | c.242del p.G81Vfs*119 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by mutect2, pindel, varscan2
- SLC25A42 | c.614T>C p.F205S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC5 | c.1278-1G>C p.X426_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- USP1 | c.2295T>G p.N765K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.292); called by muse, mutect2
- ADCY2 | c.162C>A p.V54= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1305958903; called by muse, varscan2
- ARFGEF1 | c.4656A>T p.P1552= | Silent (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- CMTM5 | c.225C>T p.F75= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as rs371218018; called by muse, mutect2, varscan2
- ECPAS | c.4908C>T p.I1636= | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- ITGA4 | c.3012C>T p.F1004= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as COSV59203089; called by muse, mutect2, varscan2
- ITPR2 | c.5940G>A p.K1980= | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- RBM4 | c.678T>A p.R226= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1271A>G | RNA (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1399G>A | RNA (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- RORA | c.197-25061A>T | Intron (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- RORA | c.197-25063G>A | Intron (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2
